Gene-level copy-number profile of tumor specimen TCGA-95-7043-01A from TCGA case TCGA-95-7043, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 63.4 years (23,165 days).
Specimen TCGA-95-7043-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.5f56b47e-4809-4bf8-b155-6ffa7ef4408b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-95-7043-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5174eb68-5e9e-426d-833a-ff8495030ab4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 1,249; copy number 2: 10,553; copy number 3: 12,317; copy number 4: 17,338; copy number 5: 7,907; copy number 6: 4,429; copy number 7: 3,993; copy number 8: 676; copy number 9: 1,202; copy number 10: 2; copy number 11: 1; copy number 16: 19; copy number 24: 4; copy number 39: 61.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-95-7043-01A-11D-1943-01): tumor purity 0.76, ploidy 3.73, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:48,932,755–49,062,081, 4 genes: RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:105,682,627–106,004,027, 5 genes (within-gene range 0–3): INTS12, GSTCD, GSTCD-AS1, NPNT, AC109361.2.
- chr8:150,584–264,703, 11 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2.
- chr12:45,718,046–47,485,722, 35 genes: AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,035 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:190,880,797–190,965,552, 2 genes, copy number 10 (within-gene range 5–10): AC005540.1, GLS.
- chr2:234,222,838–234,224,514, 1 gene, copy number 11: AC122134.1.
- chr7:120,273,175–121,441,261, 16 genes, copy number 9 (within-gene range 7–9): KCND2, RNU6-581P, AC004888.1, TSPAN12, ING3, RNA5SP240, CPED1, HMGN1P18, RNA5SP241, RNU6-517P, AC006364.1, WNT16, FAM3C, CYCSP19, AC074085.1, AC074085.2.
- chr8:37,597,480–41,032,998, 84 genes, copy number 16–39 (broad region; genes not listed).
- chr17:50,962,174–83,095,122, 932 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
